TARGET case TARGET-30-PAPRPR — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/353a11e1-4df3-5879-915e-a10265fee201

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 1 years; Vital status: Dead; Days to death: 1,585 days (4.3 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C41.0; Tissue or organ of origin: Bones of skull and face and associated joints; Classification of tumor: primary; Age at diagnosis: 1.7 years (614 days); Year of diagnosis: 2006; Days to last follow up: 1,585 days (4.3 years); Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (2 entries)
- Days to follow up: 1,207 days (3.3 years); Progression or recurrence anatomic site: Bone marrow; Days to first event: 1,207 days (3.3 years); First event: Relapse.
- Days to follow up: 1,585 days (4.3 years); Year of follow up: 2010.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAPRPR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAPRPR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1585
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
- ICDO Description: Bones of skull and face and associated joints (excludes Mandible C41.1) Calvarium Cranial bone Ethmoid bone Facial bone Frontal bone Hyoid bone Maxilla Upper jaw bone Nasal bone Occipital bone Orbital bone Parietal bone Skull, NOS Sphenoid b
